Surgical pathology report (de-identified scan), TCGA case TCGA-52-7809, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Miami, specimen TCGA-52-7809-01A (Primary Tumor).

[page 1 of 3]
Pathologic Interpretation:

- A. Right distal paratracheal R4 - [REDACTED]
- No tumor seen in one lymph node (0/1).
- B. Left distal paratracheal R4 - [REDACTED]
- No tumor seen in one lymph node (0/1).
- C. Right upper lobe lesion - [REDACTED]
- Poorly differentiated basaloid type squamous cell carcinoma, 4.5 cm.
- The tumor invades the visceral pleura but does not invade the pericardium. See note.
- Specimen resection margins free of tumor.
- Immunohistochemistry is positive for p63 and negative for chromogranin and synaptophysin.

Note: The portion of pericardium is attached to the visceral pleura by a fibrous layer of tissue

See tumor summary.

- D. Residual upper lobe - Bronchial margin:
- Bronchial margin free of tumor.
- Unremarkable lung parenchyma.
- No malignancy seen in three lymph nodes (0/3).
- E. Right distal paratracheal #4+:
- No tumor seen in one lymph node (0/1).
- F. Subcarinal #7:
- No tumor seen in one lymph node (0/1).
- G. Inferior pulmonary ligament #7:
- No tumor seen in one lymph node (0/1).
- H. Interlobar #11:
- No tumor seen in one lymph node (0/1).

Tumor Summary:

Specimen Type: Lobectomy

Laterality: right

Tumor Site: Upper lobe

Tumor Size:

- Greatest dimension: 4.5 cm

Histologic Type: Squamous cell carcinoma, basaloid type

Histologic Grade: G3: Poorly differentiated

Margins: Margins uninvolved by invasive carcinoma.

Direct Extension of Tumor: Visceral pleura

Venous (Large Vessel) Invasion (V): Absent

[page 2 of 3]
Arterial (Large Vessel) Invasion: Absent

Lymphatic (Small Vessel) Invasion (L): Absent

Regional Lymph Nodes (pN):

- pN0:

- Number examined: 7

- Number involved: 0

Pathologic Staging (pTNM): pT2, pNO, pMX

As the attending pathologist, I attest that I: (i) Examined the relevant preparation(s) for the specimen(s); and (ii) Rendered the diagnosis(es).

Intraoperative Consultation

- A. Right distal paratracheal R4 - No tumor seen in one lymph node (0/1).
- B. Left distal paratracheal R4 - No tumor seen in one lymph node (0/1).
- C. Right upper lobe lesion - Poorly differentiated carcinoma.
- D. Residual upper lobe - Bronchial margin: Bronchial margin negative for tumor.

Clinical History:

None provided

Operation Performed

Mediastinoscopy, lobectomy, right upper lobe

Pre Operative Diagnosis:

Lung disease

Specimen(s) Received:

- A: Right distal paratracheal R4
- B: Left distal paratracheal R4 -
- C: Right upper lobe lesion
- D: Residual upper lobe - Bronchial margin
- E: Right distal paratracheal #4+
- F: Subcarinal #7
- G: Inferior pulmonary ligament #7
- H: Interlobar #11

[page 3 of 3]
Gross Description:

- A. Received in formalin is a segment of tan-yellow fibroadipose tissue measuring 1 x 0.8 x 0.4 cm. The specimen is submitted in toto in one cassette for frozen.
- B. Received fresh is a segment of tan-red soft tissue measuring 1.8 x 1.2 x 0.3 cm. The specimen is submitted in toto in one cassette for frozen.
- C. Received fresh is a lung wedge measuring 13 x 6.5 x 4.6 cm. The specimen has been previously sectioned to reveal a well circumscribed indurated pale-tan to yellow lesion with focal areas of necrosis and hemorrhage measuring 4.5 x 3.7 x 3.1 cm. The lesion pushes into but does not seem to invade the visceral pleura and is present within 0.2 cm of the surface. The lesion is present 0.2 cm from an attached segment of pericardium (inked yellow). The lesion is present 4 cm from the stapled resection margin. Sectioning through the remainder of the specimen reveals a tan-white indurated calcified nodule situated 1 cm from the stapled resection margin. Cassettes are submitted as follow:
- 1 Section of the lesion submitted for frozen
- 2-3 Additional representative sections of the lesion
- 4 Section of the indurated nodule in relationship to stapled margin
- 5 Remainder of the stapled margin
- 6 Additional representative section
- 7 Uninvolved lung parenchyma
- 8-10 Tumor in relation to pleura and pericardium.
- D. Received fresh is segment of lung measuring 13 x 9 x 3.5 cm. The specimen is tan red to purple and has a smooth and glistening surface on one side, and attached tan yellow fibroconnective tissue on the other side. There is a stapled resection margin line measuring 7.9 cm, the bronchial margin is identified, it is grossly free of tumor. Serial sectioning through the specimen reveals unremarkable lung parenchyma. Sections are submitted as follow:
- 1 Bronchial margin submitted for frozen
- 2 Representative section of the stapled margin
- 3-6 One possible lymph node bisected per cassette
- E. Received in formalin is a segment of tan brown soft tissue measuring 3 x 2 x 1cm. The specimen is multisectioned submitted in toto in one cassette.
- F. Received in formalin is a segment of tan-brown soft tissue measuring 1 x 0.6 x 0.4 cm. The specimen is submitted in toto in one cassette.
- G. Received in formalin is a segment of clear tan to yellow fibroadipose tissue measuring 1 x 0.9 x 0.3 cm. The specimen is submitted in toto in one cassette.
- H. Received in formalin is a segment of pale-tan soft tissue measuring 0.9 x 0.7 x 0.3 cm. The specimen is submitted in toto in one cassette.

Source: NCI Genomic Data Commons file b455decb-9f33-4e35-89b5-55b013d44087 (TCGA-52-7809.83C514C4-6D90-4FF0-BDA1-5615AA769BBD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).